Somatic mutation profile of tumor specimen TCGA-NF-A4WU-01A (aliquot TCGA-NF-A4WU-01A-11D-A28R-08) from TCGA case TCGA-NF-A4WU, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IA; Age at diagnosis: 60.0 years (21,901 days).
Specimen TCGA-NF-A4WU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5dd1d072-47d4-4bdc-99c7-af46a643a68e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NF-A4WU-10A (Blood Derived Normal), aliquot TCGA-NF-A4WU-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cd6a0bc-6e80-4aae-9c0d-466ee27eedf4

The open-access MAF lists 35 somatic variants for this specimen: 23 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 10, Nonsense Mutation 2, In Frame Del 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 78/246 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 52/196 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57252926, COSV99916817; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 16/39 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASNS | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs149193118; called by muse, mutect2, varscan2
- ASZ1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1343852598, COSV52914933; called by muse, mutect2, varscan2
- FSCB | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as rs554125229, COSV61216671; called by muse, mutect2, varscan2
- HECW2 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs778348267; called by muse, mutect2, varscan2
- IGSF9 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100829627; called by muse, mutect2, varscan2
- KCNA3 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63901187; called by muse, mutect2, varscan2
- MAN2A2 | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs146996561; called by muse, mutect2, varscan2
- OR9K2 | c.491G>A p.R164H (on ENST00000305377; = p.R142H on NM_001005243.1) | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs751330501; called by muse, mutect2, varscan2
- PJA1 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs147196192, COSV64054024; called by muse, mutect2, varscan2
- PSMD2 | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs764804657; called by muse, mutect2, varscan2
- SAV1 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as rs1187565550, COSV61205902; called by muse, mutect2, varscan2
- SRRM2 | c.1789A>G p.R597G | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.527); catalogued as rs1176275662; called by muse, mutect2, varscan2
- ABCA3 | c.4078G>A p.D1360N | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2
- ATPSCKMT | c.667A>C p.T223P | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- G3BP2 | c.1135T>C p.F379L | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- NF1 | c.8222C>G p.T2741R (on ENST00000358273 / NM_001042492.3; = p.T2720R on NM_000267.3) | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- OR1C1 | c.667_669del p.S223del | In Frame Del (DEL) | VAF 49/102 reads (48%) | called by mutect2, pindel, varscan2
- PAPPA2 | c.4424C>A p.A1475E | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPTN | c.1552G>T p.G518C | Missense Mutation (SNP) | VAF 390/1202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ARMC3 | c.1707C>T p.N569= | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as rs370847654, COSV53062445; called by muse, mutect2, varscan2
- DNAH11 | c.7014G>A p.R2338= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- H1-5 | c.468G>T p.P156= | Silent (SNP) | VAF 32/234 reads (14%) | called by muse, mutect2, varscan2
- H4C3 | c.249A>T p.T83= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV58091093; called by muse, mutect2, varscan2
- KLHDC7A | c.1977C>T p.A659= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs1378061584, COSV68770140; called by muse, mutect2, varscan2
- LMX1B | c.366C>T p.I122= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs200350302, COSV62740594; ClinVar: likely benign; called by muse, mutect2, varscan2
- NCBP1 | c.162T>A p.A54= | Silent (SNP) | VAF 38/115 reads (33%) | called by muse, mutect2, varscan2
- SCAF1 | c.2097C>T p.F699= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs150047328; called by muse, mutect2, varscan2
- SLC6A3 | c.918C>T p.C306= | Silent (SNP) | VAF 62/174 reads (36%) | catalogued as rs746199611, COSV54366997; called by muse, varscan2
- ZNF585A | c.1432C>A p.R478= (on ENST00000292841 / NM_001288800.2; = p.R423= on NM_152655.3) | Silent (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- NACA | c.70+3691T>G | Intron (SNP) | VAF 68/125 reads (54%) | catalogued as COSV63273447; called by muse, mutect2, varscan2
- PKD1L2 | n.2805C>T | RNA (SNP) | VAF 6/19 reads (32%) | catalogued as rs746277114; called by muse, mutect2, varscan2
